CCDI case PBCJHE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/46636efa-4f82-410a-9d2a-2453cc451f19

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Small cell carcinoma, NOS: ICD-O-3 morphology code: 8041/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 14.6 years (5,315 days).

Biospecimens (3 samples)
- Samples 0DTB87, 0DTB8U (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTB8K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
